Gene-level copy-number profile of tumor specimen TCGA-CD-5813-01A from TCGA case TCGA-CD-5813, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Body of stomach; AJCC pathologic stage: Stage II; Tumor grade: G3; Age at diagnosis: 60.2 years (21,995 days).
Specimen TCGA-CD-5813-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.e29cd557-ea94-4a15-b02e-f32e1c2e78cc.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CD-5813-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 368 have no estimate.
https://portal.gdc.cancer.gov/files/0111b4a5-6ec8-4022-b1aa-4c5e3a53686d

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 4; copy number 1: 580; copy number 2: 20,033; copy number 3: 36,496; copy number 4: 1,758; copy number 5: 1,168; copy number 6: 186; copy number 7: 17; copy number 8: 8; copy number 9: 4; copy number 10: 1.

Homozygous deletions (total copy number 0; autosomes only): 4 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:36,485,343–36,485,440, 1 gene: RNA5SP181.
- chr8:20,655,184–20,700,152, 1 gene: AC018541.1.
- chr11:11,351,942–11,353,307, 2 genes: CSNK2A3, AC023946.1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 30 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:194,188,967–194,190,342, 1 gene, copy number 7: EEF1A1P14.
- chr1:239,972,787–239,974,245, 1 gene, copy number 7: AL356361.1.
- chr2:57,429,548–57,430,693, 1 gene, copy number 10: AC068276.1.
- chr3:2,362,258–2,362,738, 1 gene, copy number 7: HINT2P1.
- chr3:6,773,037–6,773,343, 1 gene, copy number 8: MRPS36P1.
- chr7:13,854,355–13,991,425, 3 genes, copy number 8: AC005019.2, AC005019.1, ETV1.
- chr8:48,515,852–48,518,157, 1 gene, copy number 7: AC026904.1.
- chr8:52,939,182–52,976,116, 2 genes, copy number 8: NPBWR1, AC009800.1.
- chr10:36,432,882–36,442,392, 4 genes, copy number 9: MTND5P17, MTND4P18, AL590730.1, AL590730.2.
- chr12:19,724,435–19,724,599, 1 gene, copy number 7: RNU1-146P.
- chr13:30,617,693–30,684,278, 2 genes, copy number 7: USPL1, Metazoa_SRP.
- chr13:30,803,206–30,996,138, 7 genes, copy number 7: LINC00398, LINC00545, TEX26-AS1, MEDAG, TEX26, AL353680.1, LINC01066.
- chr21:16,035,413–16,121,644, 3 genes, copy number 7: RNU6-426P, VDAC2P1, RPS26P5.
- chr21:16,574,718–16,590,325, 2 genes, copy number 8: AP000962.1, MIR125B2.

Autosomal genes at a single copy (total copy number 1): 452. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
